Surgical pathology report (de-identified scan), TCGA case TCGA-YU-AA61, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Barretos Cancer Hospital, specimen TCGA-YU-AA61-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD O-3
Mixed germ cell tumor 9085/3
Site @ Testis NOS C62.9
JW 3/20/14

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

1. "Left orchiectomy":

- Mixed germ cell tumor, composed of immature teratoma (50%), endodermal sinus tumor (25%) and embryonal carcinoma (25%);
- Angiolymphatic invasion not observed;
- Perineural invasion not observed;
- Rete testis infiltrated by the neoplasia;
- Spermatic cord free of neoplasia;
- Surgical margin of resection free of neoplasia.

NOTE: see also immunohistochemical exam

Other exams:

Source: NCI Genomic Data Commons file 6a0b2246-aab7-4a39-afff-b54e6daf44ca (TCGA-YU-AA61.EC40D61A-454C-4ED5-96CA-8AA5C72F1DEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).